Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016343-09A.2 (aliquot TARGET-15-SJMPAL016343-09A.2-01D) from TARGET case TARGET-15-SJMPAL016343, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,198 days).
Specimen TARGET-15-SJMPAL016343-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cdfa64b-930d-4b8e-a922-b4632c4f2cda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016343-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016343-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55fbd19e-90bd-4e10-8e40-f6b54f316e12

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Site 1, 3'UTR 1, Intron 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HEATR1 | c.6238-1G>T p.X2080_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CCND2 | c.861C>A p.I287= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV54224763; called by muse, mutect2
- CCHCR1 | c.1799-32G>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- MTERF4 | c.*1005G>T | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- POM121L4P | n.415G>A | RNA (SNP) | VAF 14/112 reads (13%) | catalogued as rs200714508; called by muse, varscan2
